Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A4U3, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A4U3-06A (Metastatic).

[page 1 of 3]
SPECIMEN(S):

A. RIGHT FRONTAL TUMOR

B. RIGHT FRONTAL TUMOR

ICD-0-3

Melanoma, NOS 8720/3

Site: brain, frontal lobe
C71.1

CLINICAL HISTORY:

Hx melanoma

lw
10/10/12

PRE-OPERATIVE DIAGNOSIS:

Right frontal brain tumor

FROZEN SECTION INTEROPERATIVE REPORT:

FSA, Brain, right frontal tumor, biopsy: Metastatic tumor consistent with melanoma

Diagnosis called in at

GROSS DESCRIPTION:

A. RIGHT FRONTAL TUMOR

Received fresh labeled with the patient's identification and designated "right frontal tumor" are multiple fragments of red-tan soft tissue measuring 2.3 x 0.9 x 0.2 CM in aggregate. Touch preparations are performed. Entirely submitted for frozen section, FSA.

B. RIGHT FRONTAL TUMOR

Received fresh labeled with the patient's identification and designated "right frontal tumor" is a portion of red-tan soft tissue measuring 4.1 x 2.9 x 0.9 CM. Sectioning shows soft red friable cut surface. One half the specimen is submitted for tissue procurement, the remainder entirely submitted, B1-B4.

DIAGNOSIS:

A. BRAIN, RIGHT FRONTAL TUMOR, BIOPSY:

- METASTATIC MELANOMA. SEE COMMENT.

[page 2 of 3]
B. BRAIN, RIGHT FRONTAL TUMOR, RESECTION:

- METASTATIC MELANOMA. SEE COMMENT.

Comment: Tumor cells are immunoreactive to S-100, Melan-A, HMB-45. Rare individual cells are weakly immunoreactive for GFAP. These findings support the diagnosis of metastatic melanoma.

SUMMARY OF IMMUNOHISTOCHEMISTRY/SPECIAL STAINS

Material: Block B4

Population: Tumor Cells

Stain/Marker:

Result:

Comment:

S-100

Positive

A103,MELAN-A

Positive

HMB 45

Positive

GFAP

Positive

rare individual tumor cells, weakly immunoreactive

[page 3 of 3]
The interpretation of the above immunohistochemistry stain or stains is guided by published results in the medical literature, provided package information from the manufacturer and by internal review of staining performance and assay validation within t

The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR). These tests were developed and their performance characteristic determined by

They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

Special stains and/or immunohistochemical stains were performed with appropriately stained positive and negative controls.

HPV/A Discrepancy		

10/10/12

Source: NCI Genomic Data Commons file 9b0b460b-834e-42cf-b8eb-6cc7dcd9f828 (TCGA-GN-A4U3.F2797B06-305A-457F-9CC7-13F7908408A8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).